Somatic mutation profile of tumor specimen HCM-CSHL-0091-C25-01A (aliquot HCM-CSHL-0091-C25-01A-11D-A77E-36) from HCMI case HCM-CSHL-0091-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 63.1 years (23,060 days).
Specimen HCM-CSHL-0091-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ff220de-6850-4f5d-b296-d91b8bf699d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0091-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0091-C25-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71826083-9453-4a47-92e2-a44ddde3639d

The open-access MAF lists 28 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Intron 4, Silent 4, 5'UTR 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>G p.V640G (on ENST00000288602 / NM_001374244.1; = p.V600G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/507 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 97/511 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATM | c.8180T>C p.V2727A | Missense Mutation (SNP) | VAF 114/425 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1565543359, COSV53738015; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.814G>T p.G272C | Missense Mutation (SNP) | VAF 117/616 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV62416962; called by muse, mutect2, varscan2
- CHRNA9 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 68/384 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771575848; called by muse, mutect2, varscan2
- PSMD14 | c.381C>G p.I127M | Missense Mutation (SNP) | VAF 75/562 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.457); catalogued as COSV68833511; called by muse, mutect2, varscan2
- PTPRJ | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 109/377 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs770381504; called by muse, mutect2, varscan2
- RPL11 | c.350A>G p.K117R (on ENST00000374550 / NM_001199802.1; = p.K118R on NM_000975.5) | Missense Mutation (SNP) | VAF 135/790 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.303); catalogued as rs773506948, COSV65778357; called by muse, mutect2, varscan2
- SCTR | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 182/685 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs146299407; called by muse, mutect2, varscan2
- ZNF610 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 68/281 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs751177289; called by muse, mutect2, varscan2
- CR1L | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 40/1037 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); called by muse, mutect2
- DDX5 | c.934A>G p.N312D | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- HCN1 | c.2410C>T p.P804S | Missense Mutation (SNP) | VAF 73/356 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IGF1R | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 83/511 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRRCC1 | c.465G>T p.Q155H | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- PAX1 | c.1330T>A p.Y444N | Missense Mutation (SNP) | VAF 68/830 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.368); called by muse, mutect2
- PLD1 | c.1327C>G p.P443A | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- CCDC6 | c.786C>T p.I262= | Silent (SNP) | VAF 45/260 reads (17%) | called by muse, mutect2, varscan2
- CRYBG1 | c.2916C>G p.S972= | Silent (SNP) | VAF 99/405 reads (24%) | called by muse, mutect2, varscan2
- FCGBP | c.11982C>T p.S3994= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs370196020; called by muse, mutect2, varscan2
- IRGC | c.1050G>A p.S350= | Silent (SNP) | VAF 87/380 reads (23%) | catalogued as rs374269776; called by muse, mutect2, varscan2
- CLDN5 | chr22:19524460 C>T | 5'Flank (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- CSNK1A1 | c.231-4543A>G | Intron (SNP) | VAF 48/272 reads (18%) | called by muse, mutect2, varscan2
- CT45A3 | c.*71A>T | 3'UTR (SNP) | VAF 33/878 reads (4%) | called by muse, mutect2
- CTRB2 | c.-15C>T | 5'UTR (SNP) | VAF 162/744 reads (22%) | called by muse, mutect2, varscan2
- PCOLCE2 | c.449-257A>T | Intron (SNP) | VAF 59/273 reads (22%) | called by muse, mutect2, varscan2
- PRSS1 | c.200+382A>C | Intron (SNP) | VAF 61/267 reads (23%) | called by muse, varscan2
- ZNF513 | c.56-38T>G | Intron (SNP) | VAF 39/275 reads (14%) | called by muse, mutect2, varscan2
